Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A94U, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A94U-01A (Primary Tumor).

[page 1 of 3]
Collect date: (MM/DD/YYYY)

ICD O-3
Adenocarcinoma, signet ring
cell 8490/3
Site: Gastric antrum C16.3
p2013/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

- "Product of subtotal gastrectomy according to standardization", "Greater omentum":

Adenocarcinoma characterized as follows:

Location: circumferential on antrum.

Type III of Borman's classification

Histological pattern(s) observed:

Tubular

Mucosecretor mucocellular with "signet ring" cells - 100% per TSS.

Mucosecretor muconodular

Solid

Other: isolated cells

Histologic grade III - poorly differentiated

Diffuse pattern of Lauren's classification

Measure of the longest axis of the tumor: 7.3 cm

Ulceration:

present

Compromise of:

mucosa

muscularis mucosae

submucosa

muscularis propria

adjacent adipose tissue

Type of tumor invasion

spiculated

Inflammatory reaction:

absent

Tumor implantation in peri-visceral adipose tissue:

present

Proximal margin

free of neoplastic involvement

Distal margin

free of neoplastic involvement

Neural infiltration:

[page 2 of 3]
present
Lymphatic vascular invasion:
present
Sanguineous vascular invasion:
present
Greater omentum:
free of neoplastic involvement.
Lymph nodes:
free of neoplastic involvement.
Discrimination of lymph nodes, according to standardization,
JGCA - 1998 (committed / dissected nodes ratio):
F - Chain 1 – right para-cardic: 0/4
H - Chain 3 - along the lesser curvature: 0/1
I - Chain 4sa - along the short gastric vessels: 0/8
K – Chain 4d - along the right gastroepiploic vessels: 0/3
L - Chain 5 - suprapyloric: 0/3
M – Chain 6 – infrapyloric: 0/7
N - Chain 7 - along the left gastric artery: 0/8
8 - Chain 8a - along the anterior hepatic artery
(anterosuperior group): 0/1
Q - Chain 9 - around the celiac trunk: 0/4
S - Chain 11p - along the proximal splenic artery: 0/1

3- "Duodenal margin":
Free of neoplastic involvement.

4 - "Gallbladder":
Nonspecific chronic cholecystitis.

Pw TSS dx discrepancy form
TCGA tumor is 100% signet ring
hw 1/2/14

HPV Discrepancy	☒	☐

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Tubular, signet ring cells, mucosecretor, solid and isolated cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	100% signet ring cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on the top slide to be sent to BCR.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director _____

Date _____

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature _____

Date _____

Source: NCI Genomic Data Commons file 548faa86-0fca-4072-9296-95098cbc7071 (TCGA-VQ-A94U.B860F6BF-6162-4565-97A4-41A4E82FBE66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).